Somatic mutation profile of tumor specimen TCGA-EX-A69L-01A (aliquot TCGA-EX-A69L-01A-11D-A32I-09) from TCGA case TCGA-EX-A69L, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 41.4 years (15,121 days).
Specimen TCGA-EX-A69L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89b92e9c-4a55-4376-a5b8-920289058b9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A69L-10A (Blood Derived Normal), aliquot TCGA-EX-A69L-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64d878b3-9de6-438a-97d6-c34212f4a2b1

The open-access MAF lists 64 somatic variants for this specimen: 44 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 39, Silent 20, Splice Site 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV55245234; called by muse, mutect2, varscan2
- ACTB | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV59320900; called by muse, mutect2, varscan2
- ADA | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV100866542, COSV65739712; called by muse, mutect2, varscan2
- AFAP1L1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV57047399; called by muse, mutect2, varscan2
- BSN | c.7585C>T p.R2529W | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs200351851, COSV56524195; called by muse, mutect2, varscan2
- CASP8 | c.550G>C p.E184Q (on ENST00000432109 / NM_033355.3; = p.G216R on NM_001228.4) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV51858195; called by muse, mutect2, varscan2
- CIITA | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV60861457; called by muse, mutect2, varscan2
- CST4 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1419553328, COSV54149611, COSV54150215; called by muse, mutect2, varscan2
- DNAJC7 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV57270184; called by muse, mutect2, varscan2
- DYNLRB1 | c.248-1G>T p.X83_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV64064260; called by muse, mutect2, varscan2
- EMSY | c.2559C>T p.V853= | Splice Region (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100596122, COSV58265226; called by muse, mutect2, varscan2
- EZH2 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57461529; called by muse, mutect2, varscan2
- FAM151B | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56475012; called by muse, mutect2, varscan2
- FBXO34 | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV58256660; called by muse, mutect2, varscan2
- GALNS | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as CM1314333, COSV51940113; called by muse, mutect2, varscan2
- GCAT | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV99959965; called by muse, mutect2, varscan2
- GEMIN5 | c.2948C>G p.S983C | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53564282; called by muse, mutect2, varscan2
- GUCY2F | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs867112346, COSV54307615; called by muse, mutect2, varscan2
- HINFP | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760606813, COSV63432352; called by muse, mutect2, varscan2
- HLA-A | c.620-1G>A p.X207_splice | Splice Site (SNP) | VAF 81/322 reads (25%) | catalogued as COSV65143650; called by muse, mutect2, varscan2
- KAT6B | c.4855G>A p.V1619I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1366652765, COSV54753553; called by muse, mutect2, varscan2
- MAGEL2 | c.2705C>T p.T902M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); catalogued as rs373945272; called by muse, mutect2, varscan2
- METTL4 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV60604693; called by muse, mutect2, varscan2
- MXRA5 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs867295958, COSV54248065; called by muse, mutect2, varscan2
- NBL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as rs765257995, COSV57030751, COSV57031207; called by muse, mutect2, varscan2
- NEU1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348861358, COSV57668955; called by muse, mutect2, varscan2
- NFKBIA | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as COSV53754587; called by muse, mutect2, varscan2
- NUCB1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs749759537, COSV54385108; called by muse, mutect2, varscan2
- OGA | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV63383075; called by muse, mutect2, varscan2
- PLXNA3 | c.5097G>T p.E1699D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV63755425; called by muse, mutect2, varscan2
- PPID | c.753-1G>A p.X251_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV56989099; called by muse, mutect2, varscan2
- PREX1 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64256050; called by muse, mutect2, varscan2
- RNF113A | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65097759; called by muse, mutect2, varscan2
- RSF1 | c.579-1G>C p.X193_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | catalogued as COSV57844932; called by muse, mutect2, varscan2
- SHBG | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs757498261, COSV52647742; called by muse, mutect2, varscan2
- SLC27A5 | c.1769G>C p.C590S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.416); catalogued as COSV54021716; called by muse, mutect2, varscan2
- SMC4 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61007529; called by muse, mutect2, varscan2
- SPIRE2 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs146263316; called by muse, mutect2, varscan2
- TAF5L | c.1351C>G p.R451G | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51088093; called by muse, mutect2, varscan2
- TBC1D16 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as COSV60478405, COSV60480875; called by muse, mutect2, varscan2
- TCF21 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV52819533; called by muse, mutect2, varscan2
- TOGARAM1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV63894601; called by muse, mutect2, varscan2
- USH2A | c.6965A>G p.N2322S | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.63); PolyPhen benign (0.341); catalogued as COSV56343309, COSV56424631; called by muse, mutect2, varscan2
- ZNF484 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV60259395; called by muse, mutect2, varscan2
- ABCC10 | c.2124C>G p.L708= (on ENST00000372530 / NM_001198934.2; = p.L680= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV55093334; called by muse, mutect2, varscan2
- ADGRA3 | c.2007G>A p.V669= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV51567556; called by muse, mutect2, varscan2
- AKAP3 | c.153G>A p.K51= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV57416225, COSV57419978; called by muse, mutect2, varscan2
- AREL1 | c.81A>T p.A27= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV62667883; called by muse, mutect2, varscan2
- CHST8 | c.783C>T p.F261= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs752123545, COSV52862703, COSV52863347; called by muse, mutect2, varscan2
- CLPTM1L | c.435C>T p.T145= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs566053718, COSV57991635; called by muse, mutect2, varscan2
- CUL1 | c.1989G>A p.L663= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV57391958; called by muse, varscan2
- ERICH3 | c.2796G>A p.E932= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs1250190199, COSV58616410; called by muse, mutect2, varscan2
- FER | c.1947G>T p.L649= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55291837, COSV99814144; called by muse, varscan2
- GJA4 | c.624C>T p.I208= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV60725984; called by muse, mutect2, varscan2
- IRGQ | c.1053C>T p.G351= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV60671377; called by muse, mutect2, varscan2
- MAU2 | c.1662C>T p.N554= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs184450529; called by muse, mutect2, varscan2
- MGA | c.8376G>T p.L2792= (on ENST00000219905 / NM_001164273.1; = p.L2583= on NM_001080541.2) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV54958720, COSV54961715; called by muse, mutect2, varscan2
- MMUT | c.2112G>A p.V704= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs1395239174, COSV51280982; called by muse, mutect2, varscan2
- MPST | c.426C>T p.L142= (on ENST00000341116 / NM_001369904.2; = p.L162= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV62018571; called by muse, mutect2, varscan2
- NUDT3 | c.279G>A p.T93= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs752382851, COSV74119148; called by muse, mutect2, varscan2
- OR51A7 | c.688T>C p.L230= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV63788902; called by muse, mutect2, varscan2
- SEC14L5 | c.546G>A p.T182= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs192935938, COSV99229472; called by muse, mutect2, varscan2
- SETX | c.1824G>C p.L608= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56393381; called by muse, mutect2, varscan2
- SRMS | c.177C>G p.L59= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs36032098; called by muse, mutect2, varscan2
